Somatic mutation profile of tumor specimen TCGA-85-8351-01A (aliquot TCGA-85-8351-01A-11D-2293-08) from TCGA case TCGA-85-8351, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.4 years (26,437 days).
Specimen TCGA-85-8351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1b58893-a2f1-4544-9167-a5708e496b8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8351-10A (Blood Derived Normal), aliquot TCGA-85-8351-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51343b78-dbe6-4d9e-a124-d52c9fdb1da3

The open-access MAF lists 155 somatic variants for this specimen: 108 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 43, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 2, 5'UTR 1, Splice Region 1, 5'Flank 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 42/69 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs541903958, COSV99360407, COSV99361155; called by muse, mutect2, varscan2
- ANKRD2 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV100080754; called by muse, mutect2, varscan2
- ANKRD30A | c.3441G>C p.Q1147H (on ENST00000611781; = p.Q1091H on NM_052997.2) | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100653081, COSV64618076; called by muse, mutect2, varscan2
- BHMT | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs911828148, COSV57155369, COSV99165381; called by muse, mutect2, varscan2
- C10orf88 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100925001, COSV64404326; called by muse, mutect2, varscan2
- C17orf80 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99277906; called by muse, mutect2, varscan2
- C9orf43 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); catalogued as COSV99928231; called by muse, mutect2, varscan2
- CAMTA1 | c.4767dup p.F1590Ifs*19 | Frame Shift Ins (INS) | VAF 54/224 reads (24%) | catalogued as rs754008719; called by mutect2, varscan2
- CATSPERG | c.1442T>A p.F481Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV99286193; called by muse, mutect2, varscan2
- CCDC102B | c.86T>C p.M29T | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100102614; called by muse, mutect2, varscan2
- CEP126 | c.3204G>T p.K1068N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99680747; called by muse, mutect2, varscan2
- CEP250 | c.7195G>T p.A2399S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100698791, COSV100699220; called by muse, mutect2, varscan2
- CLCNKA | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.51); catalogued as COSV100509931; called by muse, mutect2, varscan2
- CLEC3B | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99944521; called by muse, mutect2, varscan2
- CNR1 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV100759177; called by muse, mutect2, varscan2
- DDHD1 | c.1521C>A p.N507K (on ENST00000323669; = p.N704K on NM_030637.3) | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100079206; called by muse, mutect2, varscan2
- DEGS1 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100083299; called by muse, mutect2
- DEPDC1B | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99409456; called by muse, mutect2, varscan2
- DLAT | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99734497; called by muse, mutect2
- DNAJA2 | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as COSV100398816; called by muse, mutect2
- EEF1AKMT2 | c.607T>A p.F203I | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100766089; called by muse, mutect2, varscan2
- FAT1 | c.9803C>G p.S3268* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV71672462; called by muse, mutect2
- FAT1 | c.2248G>T p.G750* | Nonsense Mutation (SNP) | VAF 31/61 reads (51%) | catalogued as COSV101499153; called by muse, mutect2, varscan2
- FBXO15 | c.635T>C p.M212T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs142168799; called by muse, mutect2, varscan2
- GAPDHS | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99722248; called by muse, mutect2, varscan2
- GGT5 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV99571324; called by muse, mutect2, varscan2
- H2BC21 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV100479736; called by muse, mutect2, varscan2
- HOXC10 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1174683928, COSV100329030; called by muse, mutect2
- HPS1 | c.1919T>G p.M640R | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV100282394; called by muse, mutect2, varscan2
- ICA1L | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841689; called by muse, mutect2
- ICE1 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 157/579 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV99664048; called by muse, mutect2, varscan2
- IL1RAP | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs766002330, COSV99299202; called by muse, mutect2, varscan2
- JPH3 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs774198567, COSV99412999; called by muse, mutect2, varscan2
- KAT14 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100890043; called by muse, mutect2, varscan2
- KLHL5 | c.1543A>G p.K515E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV99784961; called by muse, mutect2, varscan2
- KNTC1 | c.6274A>G p.I2092V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as rs1566023288, COSV100338042; called by muse, mutect2, varscan2
- LCA5L | c.20C>G p.T7R | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99903499; called by muse, mutect2
- LMO7 | c.3148G>T p.G1050W (on ENST00000357063; = p.G731W on NM_005358.5) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100412662, COSV100412787; called by muse, mutect2, varscan2
- LRP2 | c.4561C>G p.R1521G | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99787009; called by muse, mutect2, varscan2
- LY6H | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100713862; called by muse, mutect2, varscan2
- LYST | c.11106G>T p.R3702S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV67707532; called by muse, mutect2
- MAP3K13 | c.1336T>C p.C446R | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as COSV99406611; called by muse, mutect2
- MAST2 | c.4873C>G p.Q1625E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99421509; called by muse, mutect2, varscan2
- MBP | c.709C>T p.Q237* (on ENST00000355994 / NM_001025101.2; = p.Q130* on NM_002385.3) | Nonsense Mutation (SNP) | VAF 47/219 reads (21%) | catalogued as COSV100592501; called by muse, mutect2, varscan2
- MCRS1 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.228); catalogued as COSV99234877; called by muse, mutect2, varscan2
- MIA2 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs768099235, COSV54487422; called by muse, mutect2, varscan2
- MUC17 | c.2246T>C p.L749S | Missense Mutation (SNP) | VAF 89/475 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100072149; called by muse, mutect2, varscan2
- MUC6 | c.3832G>A p.V1278I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs776231978, COSV101424438; called by muse, mutect2, varscan2
- MYOM1 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368232161; called by mutect2, varscan2
- NBEAL1 | c.6784T>A p.L2262I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100074268; called by muse, mutect2, varscan2
- NEFH | c.2394G>T p.K798N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); catalogued as COSV100151343; called by muse, mutect2, varscan2
- NEK11 | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100797590; called by muse, mutect2, varscan2
- NELL1 | c.760C>T p.L254= | Splice Region (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99040630; called by muse, mutect2, varscan2
- NRK | c.1475A>C p.Q492P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99686903; called by muse, mutect2, varscan2
- NTNG1 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV100903427; called by muse, varscan2
- OR10K1 | c.597A>G p.I199M | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV99193289; called by muse, mutect2, varscan2
- OR10K1 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV99193290; called by muse, mutect2, varscan2
- OR11L1 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100869394, COSV63315729; called by muse, mutect2, varscan2
- OR14J1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV65845869; called by muse, mutect2, varscan2
- OR2A25 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757511266, COSV68717707; called by muse, mutect2, varscan2
- OR6T1 | c.921G>T p.W307C | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100189799; called by muse, mutect2, varscan2
- OR9I1 | c.166T>A p.Y56N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100109562; called by muse, mutect2, varscan2
- PCDHA13 | c.407G>C p.S136T | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99165226; called by muse, mutect2, varscan2
- PDE5A | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV99308457; called by muse, mutect2
- PHYHIPL | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100874178; called by muse, mutect2, varscan2
- PIK3CA | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 20/185 reads (11%) | catalogued as COSV56019775, COSV99835232; called by muse, mutect2, varscan2
- PKD1 | c.9423G>T p.M3141I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as COSV99237419; called by muse, mutect2, varscan2
- PLEC | c.4718A>G p.K1573R (on ENST00000322810 / NM_201380.4; = p.K1463R on NM_000445.5) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV100511973; called by muse, varscan2
- POLM | c.203A>T p.H68L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99641700; called by muse, mutect2, varscan2
- POTED | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100203050; called by mutect2, varscan2
- PRDM9 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV57004784; called by muse, mutect2, varscan2
- PRMT8 | c.297C>A p.Y99* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | catalogued as COSV99713236; called by muse, mutect2, varscan2
- PSME4 | c.2660C>T p.T887I | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV101122329; called by muse, mutect2
- PTPN2 | c.361-1G>T p.X121_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as rs1272784542, COSV100518399; called by muse, mutect2, varscan2
- RBM46 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99907946; called by muse, mutect2, varscan2
- RPL35A | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99502156; called by muse, mutect2
- RTL1 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs775059932, COSV66016928; called by muse, mutect2, varscan2
- SALL3 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV101609951; called by muse, mutect2, varscan2
- SERPINA6 | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV100448189; called by muse, mutect2
- SERPINB9 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV66232822; called by muse, mutect2, varscan2
- SH3BP5L | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV100821976; called by muse, mutect2, varscan2
- SIX3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV53228498; called by muse, mutect2, varscan2
- SLC22A25 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV60597705, COSV60600046; called by muse, mutect2, varscan2
- SMARCC1 | c.2225A>G p.Q742R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs768188371, CM125227, COSV99592438; called by muse, mutect2, varscan2
- SOS1 | c.1645A>G p.T549A | Missense Mutation (SNP) | VAF 81/130 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1558474335, COSV101216675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVOP | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); catalogued as COSV100139255; called by muse, mutect2, varscan2
- SYNE1 | c.17956C>G p.L5986V (on ENST00000367255 / NM_182961.4; = p.L5915V on NM_033071.3) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99556383; called by muse, mutect2, varscan2
- TBX1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100226397; called by muse, mutect2, varscan2
- TLNRD1 | c.1069A>T p.N357Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV99146087; called by muse, mutect2, varscan2
- TMEM200A | c.261A>T p.K87N | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.588); catalogued as COSV51660598, COSV99758847; called by muse, mutect2
- TPCN1 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.476); catalogued as COSV59241037; called by muse, mutect2, varscan2
- TPK1 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100765448, COSV63651355; called by muse, mutect2, varscan2
- TTC14 | c.1819C>G p.Q607E | Missense Mutation (SNP) | VAF 91/434 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.985); catalogued as COSV99867719; called by muse, mutect2, varscan2
- TTN | c.12046G>A p.A4016T (on ENST00000591111; = p.A3970T on NM_003319.4) | Missense Mutation (SNP) | VAF 6/136 reads (4%) | catalogued as COSV100599771; called by muse, mutect2
- U2SURP | c.1744T>C p.S582P | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV101204371; called by muse, mutect2, varscan2
- UBR5 | c.6262G>A p.V2088I | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV55293079, COSV99639834; called by muse, mutect2, varscan2
- USP38 | c.1843G>C p.D615H | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189140, COSV61026747; called by muse, mutect2, varscan2
- VEZT | c.1249C>A p.Q417K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99703568; called by muse, mutect2, varscan2
- ZCWPW1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 115/656 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs766317643, COSV52201391; called by muse, mutect2, varscan2
- ZIC1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99291631; called by muse, mutect2, varscan2
- ZNF583 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 117/189 reads (62%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.473); catalogued as COSV99381992; called by muse, mutect2, varscan2
- ZNF721 | c.2350T>A p.F784I (on ENST00000338977; = p.F796I on NM_133474.4) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV59093443; called by muse, mutect2
- PRPF40B | c.2351dup p.K785Efs*3 (on ENST00000380281; = p.K772Efs*3 on NM_012272.3) | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- RPL5 | c.69_73+16del p.X23_splice | Splice Site (DEL) | VAF 9/84 reads (11%) | called by mutect2, pindel
- SLIT2 | c.548del p.N183Tfs*60 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.426_427del p.Q143Efs*2 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by pindel, varscan2
- THRAP3 | c.524del p.K175Sfs*68 | Frame Shift Del (DEL) | VAF 84/363 reads (23%) | called by mutect2, pindel, varscan2
- ABCD2 | c.951A>G p.K317= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100429222; called by muse, mutect2, varscan2
- AGL | c.369C>T p.P123= | Silent (SNP) | VAF 60/324 reads (19%) | catalogued as COSV99648699; called by muse, mutect2, varscan2
- APBA2 | c.2097C>A p.R699= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV101382024; called by muse, mutect2, varscan2
- ATP13A4 | c.2817C>T p.A939= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as COSV100710160; called by muse, mutect2, varscan2
- ATP2C2 | c.903C>T p.F301= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99297587; called by muse, mutect2, varscan2
- ATRX | c.3189T>C p.Y1063= | Silent (SNP) | VAF 133/206 reads (65%) | catalogued as COSV100970246; called by muse, mutect2, varscan2
- B3GNTL1 | c.432A>G p.R144= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100301767; called by muse, mutect2
- CARTPT | c.240C>T p.P80= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs746731015, COSV99703920; called by muse, mutect2, varscan2
- CHAT | c.1668C>T p.S556= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs55702495, COSV100339693, COSV60324581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CKAP2 | c.2025G>A p.R675= (on ENST00000378037 / NM_001098525.2; = p.R674= on NM_018204.5) | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as COSV99318131; called by muse, mutect2, varscan2
- FAM155A | c.1209G>A p.S403= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs778245418, COSV101027134; called by muse, mutect2, varscan2
- FZD2 | c.1092C>A p.A364= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100190283; called by muse, mutect2, varscan2
- GABRB3 | c.1324C>T p.L442= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100158669, COSV54676970; called by muse, mutect2
- IGKV1-27 | c.150C>A p.G50= | Silent (SNP) | VAF 57/118 reads (48%) | called by muse, mutect2, varscan2
- IQUB | c.864G>A p.T288= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as rs377080128; called by muse, mutect2, varscan2
- KLHL24 | c.1092C>T p.D364= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV99664777; called by muse, mutect2
- LCP1 | c.582G>T p.L194= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100549761; called by muse, mutect2, varscan2
- LSAMP | c.996C>G p.L332= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100369498; called by muse, mutect2
- MEGF11 | c.837T>C p.H279= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99987104; called by muse, mutect2, varscan2
- MYH7B | c.123C>T p.A41= | Silent (SNP) | VAF 66/175 reads (38%) | catalogued as COSV99482440; called by muse, mutect2, varscan2
- NLGN1 | c.2088C>A p.A696= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as COSV100848867, COSV64346529; called by muse, mutect2, varscan2
- NRM | c.36C>G p.L12= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99223596; called by muse, mutect2
- NRXN3 | c.897A>T p.T299= (on ENST00000557594 / NM_001272020.2; = p.T931= on NM_004796.6) | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99816730; called by muse, mutect2, varscan2
- OR10W1 | c.63G>C p.G21= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV101223626; called by muse, mutect2, varscan2
- OR8G1 | c.598C>T p.L200= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV58379537; called by muse, mutect2, varscan2
- OR9I1 | c.864G>A p.L288= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV100109560; called by muse, mutect2, varscan2
- PHYHIPL | c.324G>T p.V108= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV65848520; called by muse, mutect2, varscan2
- PIK3C3 | c.573T>C p.D191= | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as rs377659429; called by muse, mutect2
- PKD2L1 | c.945C>T p.F315= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100559323; called by muse, mutect2, varscan2
- PLCB1 | c.342C>A p.I114= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100569865; called by muse, varscan2
- POFUT1 | c.777G>T p.S259= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs146009948; called by muse, mutect2, varscan2
- POPDC3 | c.369G>A p.L123= | Silent (SNP) | VAF 258/406 reads (64%) | catalogued as COSV99633481; called by muse, mutect2, varscan2
- POTEH | c.186C>A p.G62= | Silent (SNP) | VAF 74/508 reads (15%) | catalogued as rs570524378, COSV58880865, COSV58885016; called by muse, varscan2
- PRSS16 | c.279A>C p.G93= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100041592; called by muse, mutect2, varscan2
- RNASEL | c.489G>C p.R163= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV100842557; called by muse, mutect2, varscan2
- SGK2 | c.960C>T p.A320= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs761749115, COSV58312737; called by muse, mutect2, varscan2
- SNX25 | c.1608A>G p.L536= | Silent (SNP) | VAF 65/138 reads (47%) | catalogued as COSV99252494; called by muse, mutect2, varscan2
- TCN1 | c.687G>A p.L229= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as COSV99953147; called by muse, mutect2, varscan2
- TGIF2 | c.633G>A p.E211= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as COSV100872277; called by muse, mutect2, varscan2
- TIE1 | c.2073G>C p.L691= | Silent (SNP) | VAF 53/97 reads (55%) | catalogued as COSV100992027; called by muse, mutect2, varscan2
- TRIO | c.8229G>C p.T2743= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100702468, COSV59991568; called by muse, mutect2
- UNC45A | c.1149G>A p.K383= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV101265736; called by muse, mutect2, varscan2
- ZNF445 | c.2784G>T p.P928= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs548627054, COSV101253700; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826566 G>A | 3'Flank (SNP) | VAF 39/62 reads (63%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500385 G>A | 5'Flank (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- PREP | c.-105G>C | 5'UTR (SNP) | VAF 41/320 reads (13%) | catalogued as COSV100963772; called by muse, mutect2, varscan2
- SNORD114-15 | n.8A>T | RNA (SNP) | VAF 35/185 reads (19%) | called by muse, mutect2, varscan2
